Somatic mutation profile of tumor specimen TCGA-AO-A124-01A (aliquot TCGA-AO-A124-01A-11D-A10M-09) from TCGA case TCGA-AO-A124, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct mixed with other types of carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 38.8 years (14,174 days).
Specimen TCGA-AO-A124-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0d63c88-2776-4608-bfd5-358a02a681a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A124-10A (Blood Derived Normal), aliquot TCGA-AO-A124-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d900d564-8177-4917-9d30-258931436d38

The open-access MAF lists 143 somatic variants for this specimen: 119 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 22, Nonsense Mutation 5, Frame Shift Del 4, Splice Site 3, In Frame Del 3, Frame Shift Ins 3, 3'UTR 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 136/164 reads (83%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC093827.5 | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as rs1422965797, COSV55745268; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2640C>A p.C880* | Nonsense Mutation (SNP) | VAF 41/154 reads (27%) | catalogued as COSV54450282; called by muse, mutect2, varscan2
- AGO4 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100942788, COSV64617285; called by muse, mutect2, varscan2
- AKAP14 | c.124G>C p.A42P | Missense Mutation (SNP) | VAF 105/129 reads (81%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.55); catalogued as COSV57630304; called by muse, mutect2, varscan2
- ANKRD30A | c.473T>A p.L158Q (on ENST00000611781; = p.L102Q on NM_052997.2) | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64611529; called by muse, mutect2, varscan2
- ANKRD35 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV62910469; called by muse, mutect2, varscan2
- AP2A1 | c.2617C>G p.Q873E | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58241816; called by muse, mutect2, varscan2
- APOB | c.4648C>A p.L1550M | Missense Mutation (SNP) | VAF 92/196 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51935541; called by muse, mutect2, varscan2
- APPBP2 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV50026932; called by muse, mutect2, varscan2
- BID | c.641G>A p.R214H (on ENST00000317361 / NM_197966.2; = p.R168H on NM_001196.4) | Missense Mutation (SNP) | VAF 84/101 reads (83%) | SIFT tolerated (0.26); PolyPhen benign (0.141); catalogued as rs1270911833, COSV58007036; called by muse, mutect2, varscan2
- BRCA2 | c.9911G>C p.C3304S | Missense Mutation (SNP) | VAF 85/101 reads (84%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.742); catalogued as COSV66337421; called by muse, mutect2, varscan2
- C6orf89 | c.634G>A p.G212R (on ENST00000373685; = p.G219R on NM_152734.4) | Missense Mutation (SNP) | VAF 62/282 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV62102007; called by muse, mutect2, varscan2
- CACNA2D3 | c.1646G>T p.R549L | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.757); catalogued as COSV55543373; called by muse, mutect2, varscan2
- CCR7 | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 28/107 reads (26%) | catalogued as COSV55849583; called by muse, mutect2, varscan2
- CD9 | c.8T>A p.V3D | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV50530531; called by muse, mutect2, varscan2
- CEP170 | c.3439A>G p.I1147V | Missense Mutation (SNP) | VAF 65/130 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60509534; called by muse, mutect2, varscan2
- CFTR | c.3758T>C p.L1253S | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50058072; called by muse, mutect2, varscan2
- CNTRL | c.6775C>G p.Q2259E | Missense Mutation (SNP) | VAF 62/76 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV53047742; called by muse, mutect2, varscan2
- CPNE4 | c.858T>A p.N286K | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV70194854; called by muse, mutect2, varscan2
- CRYGC | c.306G>T p.M102I | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV52205387; called by muse, varscan2
- CRYGC | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 14/15 reads (93%) | catalogued as COSV52205390; called by muse, varscan2
- CSF3R | c.353G>C p.R118P | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV100117850, COSV58967320, COSV58968650; called by muse, mutect2, varscan2
- CXorf58 | c.870A>T p.Q290H | Missense Mutation (SNP) | VAF 88/102 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV64858285; called by muse, mutect2, varscan2
- CYLC1 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.524); catalogued as COSV61410349, COSV61412581; called by muse, mutect2, varscan2
- DCC | c.2647G>A p.V883I | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs187939463, COSV59105402; called by muse, mutect2, varscan2
- DDX56 | c.1538A>G p.K513R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV51836793; called by muse, mutect2
- DLC1 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV52306666; called by muse, mutect2, varscan2
- DLEC1 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.442); catalogued as COSV57300445; called by muse, mutect2, varscan2
- DMXL1 | c.8491T>C p.Y2831H | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60712814; called by muse, mutect2, varscan2
- EPB41L3 | c.452T>C p.F151S | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59455210; called by muse, mutect2, varscan2
- EPHB4 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.94); PolyPhen benign (0.309); catalogued as COSV62269038; called by muse, mutect2, varscan2
- ERVW-1 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV71259427; called by muse, mutect2, varscan2
- ESF1 | c.2210A>C p.K737T | Missense Mutation (SNP) | VAF 122/334 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV52521296, COSV52523812; called by muse, mutect2, varscan2
- F5 | c.3200C>T p.S1067L | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as rs866332448, COSV63124248; called by muse, mutect2, varscan2
- F9 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569481975, CM045777, COSV99496348; ClinVar: uncertain significance; called by muse, mutect2
- FAM124A | c.692C>T p.P231L (on ENST00000322475 / NM_001242312.2; = p.P267L on NM_145019.4) | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1387342388, COSV54476910; called by muse, mutect2, varscan2
- FAM166A | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 140/174 reads (80%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1198263285, COSV61116912; called by muse, mutect2, varscan2
- FAM98A | c.1208G>C p.G403A | Missense Mutation (SNP) | VAF 119/389 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV53210423; called by muse, mutect2, varscan2
- FANCG | c.466C>G p.L156V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV62720747; called by muse, mutect2, varscan2
- FCGBP | c.6014A>T p.N2005I | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV55439457; called by muse, varscan2
- FKBPL | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV64322526; called by muse, mutect2, varscan2
- FRS3 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.66); PolyPhen benign (0.146); catalogued as rs1400877535, COSV52485073; called by muse, mutect2, varscan2
- GCN1 | c.7949G>A p.R2650K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs770357732, COSV56108531; called by muse, mutect2, varscan2
- GSPT1 | c.115G>T p.D39Y (on ENST00000420576 / NM_001130007.2; = p.D177Y on NM_002094.4) | Missense Mutation (SNP) | VAF 65/617 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV70452689; called by muse, mutect2, varscan2
- HECW1 | c.4813C>A p.L1605I | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.759); catalogued as COSV67830746; called by muse, mutect2, varscan2
- HELZ | c.5450C>A p.P1817Q | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV62377635, COSV62378753; called by muse, mutect2, varscan2
- HIPK1 | c.124T>G p.Y42D | Missense Mutation (SNP) | VAF 113/130 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV65784823; called by muse, mutect2, varscan2
- HSPA12A | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs555217651, COSV65022479; called by muse, mutect2, varscan2
- HTR5A | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV55280263; called by muse, mutect2, varscan2
- IFT80 | c.1707T>G p.N569K | Missense Mutation (SNP) | VAF 25/238 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.154); catalogued as COSV58448066; called by muse, mutect2
- KIF24 | c.1418C>A p.A473E | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61455440; called by muse, mutect2, varscan2
- KLF11 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV59940629; called by muse, mutect2
- KRT2 | c.986C>T p.T329I | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs776596709, COSV59010669; called by muse, mutect2, varscan2
- LEPR | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV60756262; called by muse, mutect2, varscan2
- LMAN2 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57424724; called by muse, mutect2, varscan2
- LRIT2 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV64518133, COSV64518485; called by muse, mutect2, varscan2
- LRRC27 | c.328A>G p.I110V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59809207; called by muse, mutect2, varscan2
- LRRC7 | c.985C>A p.L329I (on ENST00000651989 / NM_001370785.2; = p.L296I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV50468284; called by muse, mutect2, varscan2
- LRRK1 | c.2638G>T p.E880* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as COSV52613352; called by muse, mutect2
- LRRTM1 | c.1280A>T p.K427M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV54441785; called by muse, mutect2, varscan2
- MAN1A1 | c.1913T>C p.L638P | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs199809553, COSV63787674; called by muse, mutect2, varscan2
- MAP2K2 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs765755554, COSV53565658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K19 | c.1711A>C p.T571P | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs775516138, COSV59639297; called by muse, mutect2, varscan2
- MCOLN1 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51176135; called by muse, mutect2, varscan2
- MED13 | c.1950T>A p.S650R | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV67263540, COSV67263758; called by muse, mutect2, varscan2
- MEST | c.648-2A>C p.X216_splice | Splice Site (SNP) | VAF 80/102 reads (78%) | catalogued as COSV99784110; called by muse, mutect2, varscan2
- MIB1 | c.2811C>G p.D937E | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.785); catalogued as COSV55091072; called by muse, mutect2, varscan2
- MICAL1 | c.2832G>C p.E944D | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.028); catalogued as COSV57805474; called by muse, mutect2, varscan2
- MKRN1 | c.1294T>A p.F432I | Missense Mutation (SNP) | VAF 203/233 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV55436920; called by muse, mutect2, varscan2
- MUC16 | c.31610C>T p.T10537M | Missense Mutation (SNP) | VAF 670/746 reads (90%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as rs763136263, COSV67462177; called by muse, mutect2, varscan2
- MUC16 | c.4348C>A p.Q1450K | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as COSV67469449; called by muse, mutect2, varscan2
- MYBL2 | c.1847C>A p.S616Y | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV53830295; called by muse, mutect2, varscan2
- MYH6 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.909); catalogued as rs751285148, COSV62451058; called by muse, mutect2, varscan2
- MYOM1 | c.3841G>C p.E1281Q | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV55292744; called by muse, mutect2, varscan2
- NLRP8 | c.2613C>G p.H871Q | Missense Mutation (SNP) | VAF 65/72 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV52588373; called by muse, mutect2, varscan2
- NR6A1 | c.197G>A p.R66H (on ENST00000487099 / NM_033334.4; = p.R62H on NM_001489.5) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771035345, COSV60633711; called by muse, mutect2, varscan2
- OR13G1 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62944381; called by muse, mutect2, varscan2
- OR5B17 | c.566A>G p.E189G | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV62160375; called by muse, mutect2, varscan2
- OR6K2 | c.950C>A p.P317Q | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs762410218, COSV100656698, COSV62743546; called by muse, mutect2, varscan2
- PCYT1B | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 58/70 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as rs1353849211, COSV63265076; called by muse, mutect2, varscan2
- PRICKLE1 | c.2460A>C p.K820N | Missense Mutation (SNP) | VAF 185/391 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV58207308; called by muse, mutect2, varscan2
- PRPF4B | c.710G>C p.R237T | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV61784313; called by muse, mutect2, varscan2
- RARRES1 | c.325_326insA p.R109Qfs*12 | Frame Shift Ins (INS) | VAF 57/242 reads (24%) | catalogued as COSV52962540; called by mutect2, pindel, varscan2
- RPTOR | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV60809470; called by muse, mutect2, varscan2
- RUNDC1 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV64511898; called by muse, mutect2
- RYR2 | c.12603G>T p.Q4201H | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV63688279; called by muse, mutect2, varscan2
- RYR3 | c.7848C>G p.I2616M (on ENST00000389232; = p.I2617M on NM_001036.6) | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as COSV101213183, COSV66791809; called by muse, mutect2, varscan2
- SEMA3C | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54847587; called by muse, mutect2, varscan2
- SEMA3C | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54847611; called by muse, mutect2, varscan2
- SHE | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762087743, COSV59071928; called by muse, mutect2, varscan2
- SLC30A1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV100879139, COSV65360736, COSV65361205; called by muse, mutect2, varscan2
- SLC9A2 | c.1883C>G p.T628R | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.244); catalogued as rs1396494838, COSV52132643; called by muse, mutect2, varscan2
- SMAD7 | c.484G>C p.V162L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV50989619; called by muse, mutect2
- SMARCA2 | c.1450C>G p.H484D | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61808148; called by muse, mutect2, varscan2
- SNAP91 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 64/119 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.195); catalogued as COSV52123474; called by muse, mutect2, varscan2
- SPTA1 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63754108; called by muse, mutect2, varscan2
- SPTBN1 | c.3680C>G p.A1227G | Missense Mutation (SNP) | VAF 129/151 reads (85%) | SIFT tolerated (0.9); PolyPhen benign (0.006); catalogued as COSV61689160; called by muse, mutect2, varscan2
- STAC2 | c.1077C>G p.C359W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1472474047, COSV61065613; called by muse, mutect2, varscan2
- SYNE1 | c.21286G>C p.V7096L (on ENST00000367255 / NM_182961.4; = p.V7025L on NM_033071.3) | Missense Mutation (SNP) | VAF 157/590 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.276); catalogued as COSV54996026, COSV55107981; called by muse, mutect2, varscan2
- SYNE3 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62079805; called by muse, mutect2, varscan2
- TAF1 | c.2072A>G p.D691G (on ENST00000373790 / NM_138923.4; = p.D712G on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/135 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52114446; called by muse, mutect2, varscan2
- TBCCD1 | c.1542A>C p.T514= | Splice Region (SNP) | VAF 10/49 reads (20%) | catalogued as COSV58662284; called by muse, mutect2, varscan2
- TRIM56 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV60159267; called by muse, mutect2
- ZBBX | c.1485A>T p.K495N | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV56790769; called by muse, mutect2, varscan2
- ZNF761 | c.1594A>T p.S532C | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV61888502; called by muse, mutect2, varscan2
- ZNF761 | c.1891G>A p.E631K | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as COSV61888505; called by muse, mutect2, varscan2
- AC104452.1 | c.943_954del p.P315_G318del | In Frame Del (DEL) | VAF 25/32 reads (78%) | called by mutect2, pindel, varscan2
- CEP89 | c.808_838del p.E270Kfs*39 | Frame Shift Del (DEL) | VAF 122/574 reads (21%) | called by mutect2, pindel
- CMYA5 | c.5478del p.A1827Hfs*13 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- DAB1 | c.558+2_558+29del p.X186_splice | Splice Site (DEL) | VAF 111/231 reads (48%) | called by mutect2, pindel, varscan2
- IQGAP3 | c.3639_3671del p.Q1214_A1224del | In Frame Del (DEL) | VAF 22/54 reads (41%) | called by mutect2, pindel
- LYST | c.7781-1_7790del p.X2594_splice | Splice Site (DEL) | VAF 25/176 reads (14%) | called by mutect2, pindel, varscan2
- MNDA | c.1186del p.A396Pfs*9 | Frame Shift Del (DEL) | VAF 28/165 reads (17%) | called by mutect2, pindel, varscan2
- NIPBL | c.4269dup p.V1424Cfs*6 | Frame Shift Ins (INS) | VAF 74/158 reads (47%) | called by mutect2, pindel, varscan2
- PRLR | c.693_708del p.M232Cfs*14 | Frame Shift Del (DEL) | VAF 30/181 reads (17%) | called by mutect2, pindel
- SRPX | c.218_262del p.Q73_I87del | In Frame Del (DEL) | VAF 35/52 reads (67%) | called by mutect2, pindel
- TRBV30 | c.166G>C p.A56P | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR17 | c.253dup p.T85Nfs*11 | Frame Shift Ins (INS) | VAF 23/96 reads (24%) | called by mutect2, varscan2
- ANKRD30A | c.474G>T p.L158= (on ENST00000611781; = p.L102= on NM_052997.2) | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV64611540; called by muse, mutect2, varscan2
- AP1B1 | c.1575C>T p.I525= | Silent (SNP) | VAF 24/25 reads (96%) | catalogued as COSV58018149; called by muse, mutect2, varscan2
- DNAAF5 | c.2550C>T p.A850= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs942223896, COSV52417290; called by muse, mutect2, varscan2
- FCN1 | c.168G>T p.L56= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs775057793, COSV65662442; called by muse, mutect2, varscan2
- FSCN3 | c.456C>A p.I152= | Silent (SNP) | VAF 61/73 reads (84%) | catalogued as COSV50001110; called by muse, mutect2, varscan2
- GIMAP2 | c.123C>T p.S41= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV56235427; called by muse, mutect2, varscan2
- GLI3 | c.636G>A p.S212= | Silent (SNP) | VAF 143/309 reads (46%) | catalogued as rs369422937; called by muse, mutect2, varscan2
- LSM14B | c.825G>T p.L275= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV53380962; called by muse, mutect2, varscan2
- MROH5 | c.997C>T p.L333= | Silent (SNP) | VAF 11/12 reads (92%) | catalogued as COSV71301098; called by muse, mutect2, varscan2
- PLEKHA5 | c.2664A>G p.E888= | Silent (SNP) | VAF 53/143 reads (37%) | catalogued as COSV54701763; called by muse, mutect2, varscan2
- RC3H1 | c.2628G>C p.V876= | Silent (SNP) | VAF 47/239 reads (20%) | catalogued as COSV51201693; called by muse, mutect2, varscan2
- RNF26 | c.561C>T p.F187= | Silent (SNP) | VAF 76/85 reads (89%) | catalogued as COSV60990592; called by muse, mutect2, varscan2
- ROBO1 | c.1140A>T p.P380= | Silent (SNP) | VAF 71/89 reads (80%) | catalogued as COSV71394855; called by muse, mutect2, varscan2
- RYR2 | c.6843G>A p.V2281= | Silent (SNP) | VAF 104/647 reads (16%) | catalogued as COSV63664018, COSV63688273; called by muse, mutect2, varscan2
- SLC28A3 | c.1254C>A p.L418= | Silent (SNP) | VAF 137/176 reads (78%) | catalogued as COSV66153351; called by muse, mutect2, varscan2
- SLC44A3 | c.1275G>C p.S425= (on ENST00000271227 / NM_001114106.3; = p.S377= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/116 reads (40%) | catalogued as rs149609295, COSV54730522; called by muse, mutect2, varscan2
- SYNGR4 | c.507A>T p.R169= | Silent (SNP) | VAF 63/70 reads (90%) | catalogued as COSV61225465; called by muse, mutect2, varscan2
- TBX18 | c.915C>A p.T305= | Silent (SNP) | VAF 97/177 reads (55%) | catalogued as COSV63736982, COSV63738064; called by muse, mutect2, varscan2
- TENM1 | c.3615T>C p.D1205= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV64433101; called by muse, mutect2, varscan2
- TRIM41 | c.1890T>C p.P630= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV59319450; called by muse, mutect2, varscan2
- ZC3HAV1 | c.2670G>T p.V890= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV54296457; called by muse, mutect2, varscan2
- ZNF783 | c.435C>T p.F145= | Silent (SNP) | VAF 79/186 reads (42%) | catalogued as rs368656431; called by muse, mutect2, varscan2
- ATAD3B | c.*393G>A | 3'UTR (SNP) | VAF 29/38 reads (76%) | catalogued as rs754972620, COSV58020999; called by muse, mutect2, varscan2
- TLX1NB | n.1320dup | RNA (INS) | VAF 14/19 reads (74%) | catalogued as rs780169585; called by mutect2, varscan2
